CCDI case PBBLFD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8dae221a-54b7-4de0-a5c5-c889fec7f142

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.9 years (3,248 days).

Biospecimens (3 samples)
- Sample 0DBN9P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBNBG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBNBO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
